Somatic mutation profile of tumor specimen TCGA-MT-A51W-01A (aliquot TCGA-MT-A51W-01A-21D-A25Y-08) from TCGA case TCGA-MT-A51W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.3 years (19,098 days).
Specimen TCGA-MT-A51W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67100eb9-c92d-44c3-8ac1-17c008a539be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A51W-10A (Blood Derived Normal), aliquot TCGA-MT-A51W-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91fc1b88-31a4-4173-affb-3a7fc5fbb44f

The open-access MAF lists 68 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.11110G>C p.E3704Q | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99948651; called by muse, mutect2
- AHNAK | c.1890G>C p.K630N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99948659; called by muse, mutect2
- AP3D1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1363145772, COSV100642860; called by muse, mutect2
- APOL1 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59869724, COSV59870373; called by muse, mutect2, varscan2
- ARID4A | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV100794511; called by muse, mutect2, varscan2
- CASP5 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99507927; called by muse, mutect2, varscan2
- CBLL1 | c.1364C>A p.P455H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV56027943; called by muse, mutect2, varscan2
- CDK19 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100098902; called by muse, mutect2, varscan2
- CHAT | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100340588; called by muse, mutect2
- CRAT | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs1310824448, COSV100540069; called by muse, mutect2, varscan2
- DLX3 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101460510, COSV101460576; called by muse, mutect2, varscan2
- EPHA7 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV65195439; called by muse, mutect2
- ERBB4 | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100726611; called by muse, mutect2, varscan2
- EYS | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60987267; called by muse, mutect2
- FLT4 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV56113498; called by muse, mutect2, varscan2
- GNAS | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV100007171; called by muse, mutect2
- H2BC5 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as COSV56802601; called by muse, mutect2
- HERC1 | c.3860A>G p.Y1287C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV101496752, COSV104437847; called by muse, mutect2, varscan2
- HMCN1 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as rs1237680654, COSV99632854; called by muse, mutect2, varscan2
- MAPKAPK5 | c.854T>A p.L285Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101612322; called by muse, mutect2, varscan2
- MUC16 | c.2612A>G p.N871S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as COSV101200602; called by muse, mutect2, varscan2
- MYCL | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.179); catalogued as COSV100862366; called by muse, mutect2, varscan2
- NEBL | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV101009292; called by mutect2, varscan2
- NOS1 | c.1786A>T p.T596S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as COSV100501100, COSV57621664; called by muse, mutect2, varscan2
- NT5C1A | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs1298473734, COSV52494033; called by muse, mutect2
- OR10AG1 | c.651G>C p.L217F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100400149, COSV56632258; called by muse, mutect2
- PCDHB5 | c.760A>T p.N254Y | Missense Mutation (SNP) | VAF 106/337 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99169294; called by muse, mutect2, varscan2
- PHF1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100992652; called by muse, mutect2, varscan2
- PHF2 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1478065396, COSV100823272; called by muse, mutect2, varscan2
- PLCE1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs754397478, COSV53376651; called by muse, mutect2
- PLEKHA6 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99692466; called by muse, mutect2, varscan2
- PNPT1 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs1185622350, COSV99570316; called by muse, mutect2, varscan2
- PTPRE | c.944A>T p.K315M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV99618506; called by muse, mutect2, varscan2
- SNRNP25 | c.373T>C p.F125L (on ENST00000383018; = p.F116L on NM_024571.4) | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs762979091, COSV99244930; called by muse, mutect2, varscan2
- SNTG1 | c.811-1G>C p.X271_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99385061; called by muse, mutect2
- SPEN | c.2754G>T p.Q918H | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV101005482; called by muse, mutect2, varscan2
- SPHK2 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1321130229, COSV55338579; called by muse, mutect2, varscan2
- TEX55 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99817339, COSV99817672; called by muse, mutect2, varscan2
- TEX55 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV99817674; called by muse, varscan2
- TEX55 | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV99817677; called by muse, varscan2
- TUT7 | c.3428G>C p.R1143T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99463387; called by muse, mutect2, varscan2
- TXK | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.908); catalogued as COSV99972670; called by muse, mutect2
- UBR7 | c.1247G>C p.R416T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV99184322; called by muse, mutect2, varscan2
- VPS13C | c.3065C>G p.S1022C (on ENST00000644861 / NM_020821.3; = p.S979C on NM_017684.5) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99829473; called by muse, mutect2, varscan2
- WNK1 | c.4673C>G p.S1558C (on ENST00000315939 / NM_018979.4; = p.S1311C on NM_014823.3) | Missense Mutation (SNP) | VAF 90/501 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100268004; called by muse, mutect2, varscan2
- ZNF614 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99571878; called by muse, mutect2, varscan2
- ZNF804B | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100305011; called by muse, mutect2
- ZSCAN29 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV99539265; called by muse, mutect2, varscan2
- DHRS4 | c.286dup p.R96Pfs*36 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- YME1L1 | c.1700dup p.M567Ifs*16 (on ENST00000326799 / NM_139312.3; = p.M510Ifs*16 on NM_014263.4) | Frame Shift Ins (INS) | VAF 23/142 reads (16%) | called by mutect2, pindel, varscan2
- ZBTB24 | c.1526dup p.L509Ffs*5 | Frame Shift Ins (INS) | VAF 23/137 reads (17%) | called by mutect2, pindel, varscan2
- ZNF616 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- AHNAK | c.10800G>C p.L3600= | Silent (SNP) | VAF 32/313 reads (10%) | catalogued as COSV99948656; called by muse, mutect2, varscan2
- CCDC180 | c.3438T>C p.L1146= | Silent (SNP) | VAF 30/253 reads (12%) | catalogued as rs759792444, COSV100827118; called by muse, mutect2, varscan2
- DACT1 | c.2139C>T p.Y713= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs778935261, COSV60019654; called by muse, mutect2, varscan2
- DST | c.14241C>T p.S4747= (on ENST00000361203 / NM_001374722.1; = p.S2335= on NM_015548.5) | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs746641066, COSV99758451; called by muse, mutect2, varscan2
- GRIN2B | c.1350G>A p.P450= | Silent (SNP) | VAF 44/226 reads (19%) | catalogued as rs200607718, COSV101663124, COSV74206392; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSP90AB1 | c.1834C>A p.R612= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as rs373017568; called by muse, mutect2
- PARP1 | c.1386C>G p.V462= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100828999; called by muse, mutect2, varscan2
- PRDM14 | c.678C>A p.L226= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99400379; called by muse, mutect2
- SLC5A5 | c.255C>G p.L85= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99715244; called by muse, mutect2, varscan2
- SLITRK3 | c.514C>T p.L172= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99579711; called by muse, mutect2, varscan2
- SRCAP | c.9162C>G p.S3054= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99350828; called by muse, mutect2, varscan2
- SUSD4 | c.975C>T p.F325= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1318094933, COSV59552072; called by muse, mutect2
- UBE3C | c.1164A>G p.V388= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1563047082, COSV100780024; called by muse, mutect2, varscan2
- ZNF616 | c.1422C>T p.F474= | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as COSV57510917; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505778 A>C | 5'Flank (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
